Somatic mutation profile of tumor specimen TCGA-G9-6353-01A (aliquot TCGA-G9-6353-01A-11D-1961-08) from TCGA case TCGA-G9-6353, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.1 years (21,221 days).
Specimen TCGA-G9-6353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a7f40aa-436b-4f15-9fe2-879272479f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6353-10A (Blood Derived Normal), aliquot TCGA-G9-6353-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/defb0bd4-129e-4303-9c26-8f7c456d1362

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD19 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs763382763, COSV58570894; called by muse, mutect2
- PCDHA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs781791401, COSV63538555; called by muse, mutect2
- IL2RB | c.1444C>T p.L482= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1489172785, COSV53424751; called by muse, mutect2
